Surgical pathology report (de-identified scan), TCGA case TCGA-G9-6364, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G9-6364-01A (Primary Tumor).

[page 1 of 4]
SPECIMENS:

- A. RIGHT DISTAL URETER
- B. LEFT DISTAL URETER
- C. BLADDER AND PROSTATE
- D. LEFT ILIAC VEIN LYMPH NODES
- E. LEFT ILIAC ARTERY LYMPH NODES
- F. LEFT OBTURATOR LYMPH NODES
- G. LEFT COMMON ILIAC LYMPH NODES
- H. RIGHT ILIAC VEIN LYMPH NODES
- I. RIGHT ILIAC ARTERY LYMPH NODES
- J. RIGHT OBTURATOR LYMPH NODES
- K. RIGHT COMMON ILIAC LYMPH NODES
- L. LEFT DISTAL URETER FINAL MARGIN
- M. RIGHT DISTAL URETER FINAL MARGIN

TCGA - G9 - 6364

SPECIMEN(S):

- A. RIGHT DISTAL URETER
- B. LEFT DISTAL URETER
- C. BLADDER AND PROSTATE
- D. LEFT ILIAC VEIN LYMPH NODES
- E. LEFT ILIAC ARTERY LYMPH NODES
- F. LEFT OBTURATOR LYMPH NODES
- G. LEFT COMMON ILIAC LYMPH NODES
- H. RIGHT ILIAC VEIN LYMPH NODES
- I. RIGHT ILIAC ARTERY LYMPH NODES
- J. RIGHT OBTURATOR LYMPH NODES
- K. RIGHT COMMON ILIAC LYMPH NODES
- L. LEFT DISTAL URETER FINAL MARGIN
- M. RIGHT DISTAL URETER FINAL MARGIN

GROSS DESCRIPTION:

A. RIGHT DISTAL URETER

Received fresh for frozen section is a tan pink tubular segment of ureter 0.6 x 0.3 x 0.3 cm. A portion of the specimen is submitted in FSA. The remainder is submitted in A2.

B. LEFT DISTAL URETER

Received fresh for frozen section is a tan pink tubular segment of ureter 0.5 x 0.3 x 0.3 cm. A portion of the specimen is submitted in FSB. The remainder is submitted in B2.

C. BLADDER AND PROSTATE

Specimen consists of cystectomy and prostatectomy specimen measuring 15.0 x 10.0 x 5.5 cm. The specimen is inked as follows: right, green; left, yellow; posterior, black; anterior, orange; apex, red. The distal urethral margin was taken and submitted as C1. Cross section of prostate reveals solid tan surfaces without areas of necrosis or hemorrhage. The urinary bladder mucosa contains depressed area in the left lateral wall measuring 1.0 x 0.8 cm. Serial cross sections of the bladder wall reveal a solid mass in the left lateral wall measuring 2.8 x 2.4 x 1.5 cm. The mass extends within 2 mm from the inked surface. The right ureter is identified and measures 3.2 cm in length and 0.4 cm in diameter. The left ureter is identified and measures 2.5 cm in length and 0.4 cm in diameter. Portion of prostatic tissue is sent for tissue procurement. Sections are submitted as follows (the entire remaining prostatic tissue is submitted for microscopic evaluation):

- C1: urethral margin (distal margin)
- C2: right prostate
- C3: left prostate
- C4-C5: Transition of urinary bladder and prostate (C4, right; C5, left)
- C6: trigone
- C7-C13: left wall tumor with left ureteral opening in C13
- C14: right lateral wall
- C15: posterior wall
- C16-C17: Superior wall (C16, right; C17, left)
- C18-C19: random sections of attached adipose tissue
- C20: right ureteral margin
- C21: left ureteral margin
- C22 to C26: left prostate
- C27 to C34: right prostate

[page 2 of 4]
D. LEFT ILIAC VEIN LYMPH NODE

Received in formalin are two tan pink lymph nodes 0.3 x 0.2 x 0.2 cm and 0.2 x 0.2 x 0.2 cm. The specimen is entirely submitted in D1 and D2.

E. LEFT ILIAC ARTERY LYMPH NODE

Received in formalin are two tan pink lymph nodes 2 x 1 x 1 cm and 1 x 0.5 x 0.5 cm. The specimen is entirely submitted in E1 and E2.

F. LEFT OBTURATOR LYMPH NODE

Received in formalin are three tan pink lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 0.7 x 0.5 x 0.5 cm. The specimen is entirely submitted in F1 (lymph nodes) and F2 (lymph node).

G. LEFT COMMON ILIAC LYMPH NODE

Received in formalin are two tan pink lymph nodes 0.3 x 0.3 x 0.3 cm to 0.7 x 0.5 x 0.4 cm. The specimen is entirely submitted in G1.

H. RIGHT ILIAC VEIN LYMPH NODE

Received in formalin are seven tan pink lymph nodes ranging from 0.2 x 0.2 x 0.2 cm to 0.8 x 0.4 x 0.4 cm. The specimen is entirely submitted in H1 and H2.

I. RIGHT ILIAC ARTERY LYMPH NODE

Received in formalin are two tan pink lymph nodes 0.3 x 0.3 x 0.2 cm and 0.6 x 0.5 x 0.5 cm. The specimen is entirely submitted in I1.

J. RIGHT OBTURATOR LYMPH NODE

Received in formalin are five tan pink lymph nodes ranging from 0.5 x 0.4 x 0.4 cm to 2.2 x 0.6 x 0.5 cm. The specimen is entirely submitted in J1 to J3 (J2 one lymph node).

K. RIGHT COMMON ILIAC LYMPH NODE

Received in formalin is a tan pink lymph node 0.5 x 0.3 x 0.3 cm. The specimen is entirely submitted in K1.

L. LEFT DISTAL URETER FINAL MARGIN

Specimen consists of a piece of ureter measuring 1.0 cm in length and 0.4 cm in diameter. The tissue is sliced perpendicular to ureter into three pieces and completely submitted in L1.

M. RIGHT DISTAL URETER FINAL MARGIN

Specimen consists of a piece of ureter measuring 1.0 cm in length and 0.4 cm in diameter. The tissue is bisected and completely submitted in M1.

DIAGNOSIS:

A. URETER, RIGHT DISTAL, EXCISION:

- URETERAL TISSUE, NO CARCINOMA SEEN

B. LEFT DISTAL URETER, EXCISION:

- URETERAL TISSUE, NO CARCINOMA SEEN

C. URINARY BLADDER AND PROSTATE, RADICAL CYSTOPROSTATECTOMY:

- URINARY BLADDER:

- INVASIVE HIGH-GRADE UROTHELIAL CARCINOMA, WITH SMALL CELL CARCINOMA (80%) AND ADENOCARCINOMA (20%) COMPONENTS, FOCALLY INVADING PERIVESICAL ADIPOSE TISSUE

- TUMOR SIZE 2.8 X 2.4 X 1.5 CM

- MARGINS NEGATIVE FOR CARCINOMA (CARCINOMA LOCATED 1 MM FROM INKED RADIAL MARGIN)

- NO CARCINOMA SEEN IN FIVE PERIVESICAL SMALL LYMPH NODES (0/5)

- CYSTITIS CYSTICA, CHRONIC INFLAMMATION, AND GIANT CELL GRANULOMAS

- SEE NOTE AND SYNOPTIC REPORT

- PROSTATE:

- PROSTATIC ADENOCARCINOMA INVOLVING RIGHT AND LEFT SIDE ASPECTS OF THE PROSTATE

- GLEASON#S GRADE 3 + 4 (SCORE 7/10)

- FOCAL EXTRAPROSTATIC FAT INVOLVEMENT SEEN, RIGHT SIDE

- MARGINS NEGATIVE FOR CARCINOMA

- SEE NOTE AND SYNOPTIC REPORT

D. LYMPH NODES, LEFT ILIAC VEIN, EXCISION:

- NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2)

[page 3 of 4]
E. LYMPH NODES, LEFT ILIAC ARTERY, EXCISION:
- NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2)

F. LYMPH NODES, LEFT OBTURATOR, EXCISION:
- NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2)

G. LYMPH NODES, LEFT COMMON ILIAC, EXCISION:
- NO CARCINOMA SEEN IN THREE LYMPH NODES (0/3)

H. LYMPH NODES, RIGHT ILIAC VEIN, EXCISION:
- NO CARCINOMA SEEN IN SEVEN LYMPH NODES (0/7)

I. LYMPH NODES, RIGHT ILIAC ARTERY, EXCISION:
- NO CARCINOMA SEEN IN TWO LYMPH NODES (0/2)

J. LYMPH NODES, RIGHT OBTURATOR, EXCISION:
- NO CARCINOMA SEEN IN SIX LYMPH NODES (0/6)

K. LYMPH NODE, RIGHT COMMON ILIAC, EXCISION:
- NO CARCINOMA SEEN IN ONE LYMPH NODE (0/1)

L. URETER, LEFT DISTAL FINAL MARGIN, EXCISION:
- URETERAL TISSUE, NO CARCINOMA SEEN

M. URETER, RIGHT DISTAL FINAL MARGIN, EXCISION:
- URETERAL TISSUE, NO CARCINOMA SEEN

NOTE: The urothelial carcinoma is composed of two components; one with morphologic features of small cell carcinoma and the other with glandular differentiation with mucinous features. The carcinomas seen in the urinary bladder and prostate are cyto-/ histomorphologically different and exhibit features consistent with their primary anatomic locations. The prostatic carcinoma is seen in four out of fifteen tissue sections (about 5-10% of the evaluated prostatic tissue). Dr. has seen representative slides of this case and agreed. Verbal report was given to Dr.

SYNOPTIC REPORT - URINARY BLADDER, URETER AND RENAL PELVIS

Specimen Type: Radical cystoprostatectomy
Tumor Site: Left lateral wall
Tumor Size: Greatest dimension: 2.8cm
Additional dimensions: 2.4cm
WHO Classification
Infiltrating urothelial carcinoma 8120/3
High Grade
Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent
Perineural Invasion: Absent
Direct Extension of Invasive Tumor: Perivesical fat
Lymph nodes: Negative 0 / 30
Margins of Resection: Free
Additional Pathologic Findings: Inflammation/regenerative changes
Cystitis cystica glandularis
Pathological Staging (pTNM): T 3a N 0 M x

SYNOPTIC REPORT - PROSTATE GLAND

Location: Left
Right
WHO CLASSIFICATION
Epithelial tumors
Adenocarcinoma 8140/3
Multicentricity: Yes
Gland Involvement: 8%
Gleason Grade/Sum:: Grade 3 + 4 , Sum 7

[page 4 of 4]
[REDACTED]

High Grade PIN Present: Yes
Perineural Invasion: Yes
Vascular/Lymphatic Invasion: No
Seminal Vesicle Invasion: No
Periprostic Fat Involved: Yes
Details: Right side
Bladder Neck Involved: No
Margins Involvement: No
Frozen Performed: No
Post Hormonal Therapy Change: No
Lymph Nodes: Negative
Other Pathologic Findings: BPH
Pathological Staging (pTNM): T 3a N 0 M x

CLINICAL HISTORY:

None provided

PRE-OPERATIVE DIAGNOSIS:

Bladder carcinoma

INTRAOPERATIVE CONSULTATION:

FSA and FSB. Right and left distal ureters: Negative for tumor. Diagnosis called to Dr. [REDACTED] by Dr. [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 402e6151-7281-4891-89af-0818a789add9 (TCGA-G9-6364.81DEB5A1-4D5D-490A-A956-A64A4E6763F8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).